Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6384, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6384-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

TCGA-G9-6384

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODES
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODES

Received fresh for frozen section labeled with the patient's identification and 'right pelvic lymph nodes' are multiple tan pink fragments of soft tissue aggregating to 5.5 x 3.5 x 1cm. The specimen is probed for lymph nodes. Entirely submitted in FSA1-FSA2.

B. LEFT PELVIC LYMPH NODES

Received fresh for frozen section labeled with the patient's identification and 'left pelvic lymph nodes' are multiple tan pink fragments of soft tissue aggregating to 2.5 x 2 x 0.8cm. The specimen is probed for lymph nodes. Entirely submitted in FSB.

C. PROSTATE

Received fresh labeled with the patient's identification and designated "prostate" is an intact prostatectomy specimen with white plastic catheter weighing 29 g and measuring 3.6 CM from right to left, 3.5 CM from anterior to posterior, and 2.9 CM from apex to base. The capsule is smooth and red. Ink code: Apex-red, anterior-orange, posterior-black, base-blue, right lateral-green, left lateral-yellow. The apex and base are removed from the specimen to yield a new weight of 12 g. The specimen is serially sectioned from apex to base to show a red inflamed area in the mid portion surrounding the urethra measuring 2.5 x 1.8 x 0.8 CM. The remainder of the prostate parenchyma shows fibrous tan tissue. The right and left seminal vesicles, 3.2 x 1.5 x 0.7, and 2.5 x 1.5 x 0.4 CM, respectively, are bisected to show beige tan cystic tissue. The right and left vas deferens, 2.6 x 0.5, and 1.5 x 0.5 CM, respectively, are serially sectioned to show firm tan tube structure. A portion of the specimen is submitted for tissue procurement, the remainder entirely submitted:

C1-C2: Right Apex

C3-C4: Left apex

C5: Level I right side

C6: Level I left side

C7: Level II capsule, right side

C8: Level II capsule, left side

C9-C10: Right lateral base

C11-C13: Right base

C14: Right base with proximal urethral margin

C15: Left base with proximal urethral margin

C16-C17: Left base

C18-C19: Left lateral base

C20: Representative section (s) right seminal vesicle, right vas deferens

C21: Representative section (s) left seminal vesicle, left vas deferens

DIAGNOSIS:

A. LYMPH NODES, RIGHT PELVIS, BIOPSY:

-ELEVEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/11)

B. LYMPH NODES, LEFT PELVIS, BIOPSY:

-THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3)

C. PROSTATE, PROSTATECTOMY:

- PROSTATIC ADENOCARCINOMA GLEASON SCORE 3+4 = 7,
INVOLVING APPROXIMATELY 14% OF THE EXAMINED PROSTATIC TISSUE.

- CARCINOMA IS PRESENT FOCALLY AT THE LEFT APEX AND THE LEFT
LATERAL BASE WITH EXTENSION INTO THE PERIPROSTATIC ADIPOSE
TISSUE (SEE NOTE)

- PERINEURAL INVASION IS IDENTIFIED

- NO SEMINAL VESICLE INVOLVEMENT IS PRESENT

- SURGICAL MARGIN NEGATIVE

[page 2 of 2]
[REDACTED]

- SEE SYNOPTIC REPORT.

NOTE: There is carcinoma present in the left apex measuring less than 1 mm from the inked anterior/posterior margin, and carcinoma present in the left lateral base with extension into the periprostic adipose tissue 1.5 mm from the inked anterior and posterior margins. Clinical and radiographic correlation and is warranted.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: A: RIGHT PELVIC LYMPH NODES

B: LEFT PELVIC LYMPH NODES

C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Basal

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 14%

Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

High Grade PIN Present: Yes

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostic Fat Involved: Yes

Details: Anterior and posterior left lateral base, left level II

Bladder Neck Involved: No

Margins Involvement: No

Frozen Performed: No

Lymph Nodes: Negative Right 0 / 11 Left 0 / 3

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 3a N 0 M X

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

pMX: Cannot be assessed

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma.

INTRAOPERATIVE CONSULTATION:

■ FSA1/FSA2-FSB: Right-left pelvic lymph nodes: Negative for carcinoma. Diagnosis called to Dr. at [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file c763a891-ffde-4d96-841e-aa3e47a6be5a (TCGA-G9-6384.6987C1C1-6E23-44F0-BBA8-6BBA4A288025.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).